Somatic mutation profile of tumor specimen TCGA-FG-8188-01A (aliquot TCGA-FG-8188-01A-11D-2253-08) from TCGA case TCGA-FG-8188, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 41.2 years (15,051 days).
Specimen TCGA-FG-8188-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7bbaa613-181e-4a3d-8b65-6c73ad9caa53.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-8188-10A (Blood Derived Normal), aliquot TCGA-FG-8188-10A-01D-2253-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e47307ca-c52c-4db3-8240-c11567812959

The open-access MAF lists 34 somatic variants for this specimen: 23 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 10, Frame Shift Del 2, Splice Site 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 45/120 reads (38%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3R1 | c.1679A>G p.D560G (on ENST00000521381 / NM_181523.3; = p.D290G on NM_181504.4) | Missense Mutation (SNP) | VAF 25/124 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV57125813; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 12/26 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 53/129 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen possibly damaging (0.45); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACOT9 | c.358C>A p.L120I | Missense Mutation (SNP) | VAF 47/62 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60539172; called by muse, mutect2, varscan2
- BACH2 | c.820C>T p.Q274* | Nonsense Mutation (SNP) | VAF 50/113 reads (44%) | catalogued as COSV57611968; called by muse, mutect2, varscan2
- CCL3L3 | c.44T>C p.M15T | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs1441638444; called by muse, mutect2, varscan2
- CDH23 | c.5822A>G p.D1941G | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.81); catalogued as COSV56495108; called by muse, varscan2
- COL9A2 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated, low confidence (0.5); PolyPhen possibly damaging (0.499); catalogued as rs201243011, COSV65608233; called by muse, mutect2, varscan2
- CRHBP | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1261191988, COSV57190380; called by muse, mutect2, varscan2
- DEFB112 | c.164A>G p.Y55C | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59183076; called by muse, mutect2, varscan2
- DEFB113 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.086); catalogued as COSV59038669; called by muse, mutect2
- FMR1 | c.377T>C p.F126S | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54428229; called by muse, mutect2, varscan2
- NADSYN1 | c.92A>G p.E31G | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as COSV59811262, COSV59815704; called by muse, mutect2, varscan2
- PRKDC | c.10606A>G p.S3536G | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV58066917; called by muse, mutect2, varscan2
- RARS2 | c.836T>G p.V279G | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV65763208; called by muse, mutect2, varscan2
- RB1CC1 | c.2335G>A p.D779N | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.012); catalogued as rs368359280, COSV50283157; called by muse, mutect2, varscan2
- SF3A3 | c.1171-1G>T p.X391_splice | Splice Site (SNP) | VAF 15/49 reads (31%) | catalogued as COSV65957016; called by muse, mutect2, varscan2
- SLC9A2 | c.2152C>G p.Q718E | Missense Mutation (SNP) | VAF 31/186 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV52139042; called by muse, mutect2, varscan2
- TTN | c.1756G>C p.E586Q | Missense Mutation (SNP) | VAF 8/198 reads (4%) | PolyPhen possibly damaging (0.756); catalogued as COSV60107768, COSV60411155; called by muse, mutect2
- UBXN7 | c.626A>T p.D209V | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV56358331; called by muse, mutect2, varscan2
- ATRX | c.1274_1275del p.K425Rfs*8 | Frame Shift Del (DEL) | VAF 67/119 reads (56%) | called by mutect2, pindel, varscan2
- MKRN1 | c.1209_1210del p.K404Sfs*20 | Frame Shift Del (DEL) | VAF 66/247 reads (27%) | called by mutect2, pindel, varscan2
- APLNR | c.1131T>C p.L377= | Silent (SNP) | VAF 26/65 reads (40%) | catalogued as rs751341256, COSV57244302; called by muse, mutect2, varscan2
- GPC4 | c.501C>T p.R167= | Silent (SNP) | VAF 23/118 reads (19%) | catalogued as COSV63700249; called by muse, mutect2, varscan2
- GRM7 | c.1779T>C p.I593= | Silent (SNP) | VAF 10/145 reads (7%) | catalogued as COSV63177217; called by muse, mutect2
- KATNIP | c.4353G>A p.V1451= | Silent (SNP) | VAF 15/98 reads (15%) | catalogued as COSV55184461, COSV55194036; called by muse, mutect2, varscan2
- KRTAP10-12 | c.18C>T p.S6= | Silent (SNP) | VAF 35/236 reads (15%) | catalogued as rs191466912, COSV59983201; called by muse, mutect2, varscan2
- PIK3R1 | c.387G>A p.P129= | Silent (SNP) | VAF 35/434 reads (8%) | catalogued as rs201402919, COSV57128333; called by muse, mutect2
- RAMP3 | c.360C>T p.I120= | Silent (SNP) | VAF 18/304 reads (6%) | catalogued as COSV54244844; called by muse, mutect2
- RYR3 | c.1890C>G p.L630= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as COSV66808526, COSV66811378; called by muse, mutect2, varscan2
- TENM3 | c.2043T>C p.C681= | Silent (SNP) | VAF 74/195 reads (38%) | catalogued as COSV69322084; called by muse, mutect2, varscan2
- VPS13D | c.11859T>C p.F3953= | Silent (SNP) | VAF 46/113 reads (41%) | catalogued as rs1327089454, COSV50706126; called by muse, mutect2, varscan2
- SLC7A2 | c.-22-4485A>G | Intron (SNP) | VAF 19/93 reads (20%) | catalogued as rs1398557769, COSV50279754; called by muse, mutect2, varscan2
